Somatic mutation profile of tumor specimen 0DVU3J from CCDI case PBCJXE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Meningioma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 14.3 years (5,229 days).
Specimen 0DVU3J: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5a9b4bb3-8817-48a3-a919-ce8c8575ba0b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVU3S (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7444aaf0-613a-47e8-a436-f5f9b9adde7b

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Nonsense Mutation 2, Missense Mutation 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DTD2 | c.16C>T p.R6W | Missense Mutation (SNP) | VAF 16/85 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.425); catalogued as rs17097904; called by muse, mutect2, varscan2
- NF2 | c.592C>T p.R198* | Nonsense Mutation (SNP) | VAF 66/187 reads (35%) | catalogued as rs1555993345, CM950856, COSV58519797; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CCDC18 | c.3880A>T p.K1294* (on ENST00000343253 / NM_001306076.1; = p.K1295* on NM_206886.4) | Nonsense Mutation (SNP) | VAF 24/213 reads (11%) | called by muse, varscan2
- HLTF | c.2692C>G p.Q898E | Missense Mutation (SNP) | VAF 26/799 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- HERC1 | c.13689-48A>T | Intron (SNP) | VAF 6/50 reads (12%) | called by muse, varscan2
